TCGA case TCGA-44-7670 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9b38eded-3f46-4aaa-9991-68008d97bdbe

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 47 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 47.6 years (17,392 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 88 days; Days to treatment end: 165 days; Number of cycles: 4; Treatment dose: 419 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 88 days; Days to treatment end: 165 days; Number of cycles: 4; Treatment dose: 420 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the vulva (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 531 days (1.5 years); Disease response: Tumor Free.
- Days to follow up: 882 days (2.4 years); Disease response: Tumor Free.

Other clinical attributes
- DLCO (% of predicted): 50; FEV1/FVC after bronchodilator (%): 90; FEV1/FVC before bronchodilator (%): 86; FEV1 after bronchodilator (% of reference): 82; FEV1 before bronchodilator (% of reference): 80.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 30; Tobacco smoking onset year: 1980.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-44-7670-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.8; Shortest dimension: 0.7.
  Slide TCGA-44-7670-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 5.
- Sample TCGA-44-7670-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-44-7670-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-44-7670-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.5; Intermediate dimension: 0.9; Shortest dimension: 0.7.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Anatomic organ subdivision: L-Upper; Pulmonary function test indicator: Yes.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; New tumor event surgery: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Vulva.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy of the vulva. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 882 days; disease-specific survival: no event (censored), 882 days; disease-free interval: no event (censored), 882 days; progression-free interval: no event (censored), 882 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-44-7670-01A-11D-2062-01): tumor purity 0.5, ploidy 4.89, whole-genome doublings 2.
